Gene-level copy-number profile of tumor specimen TCGA-XP-A8T8-01A from TCGA case TCGA-XP-A8T8, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 49.4 years (18,048 days).
Specimen TCGA-XP-A8T8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.f0dbb905-1b23-4aca-9dce-d7d2b73f6d3a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XP-A8T8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 829 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/836b3ca8-718e-4287-b47b-5a3541ce22c2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,111; copy number 2: 22,453; copy number 3: 24,481; copy number 4: 7,678; copy number 5: 1,552; copy number 6: 154; copy number 7: 921; copy number 8: 157; copy number 9: 121; copy number 10: 64; copy number 11: 39; copy number 13: 5; copy number 15: 12; copy number 19: 26; copy number 31: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XP-A8T8-01A-11D-A36I-01): tumor purity 0.64, ploidy 2.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,365 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,810,378–31,065,991, 7 genes, copy number 8 (within-gene range 3–8): AL137027.1, LINC01778, RN7SKP91, AL445235.1, SDC3, RN7SL371P, PUM1.
- chr3:140,865,075–194,832,592, 878 genes, copy number 7 (broad region; genes not listed).
- chr5:21,750,673–22,853,344, 1 gene, copy number 8 (within-gene range 5–8): CDH12.
- chr5:22,139,247–26,484,711, 48 genes, copy number 8: AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, AC113370.1, RNU4-43P, AC025475.1, AC025475.2.
- chr11:45,486,867–47,164,385, 49 genes, copy number 8 (within-gene range 2–8): AC103855.2, AC103855.4, AC103855.1, CHST1, AC087442.1, MIR7154, AC044839.1, AC044839.2, LINC02690, LINC02716, SLC35C1, AC044839.3, CRY2, MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4, AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1, HARBI1, ATG13, ARHGAP1, ZNF408, F2, CKAP5, MIR5582, AC115088.1, SNORD67, LRP4-AS1, LRP4, AC021573.1, C11orf49, AC103792.1.
- chr11:69,294,151–71,252,577, 46 genes, copy number 19–31 (within-gene range 2–31): MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr18:47,390–6,415,237, 126 genes, copy number 9–13 (within-gene range 4–13) (broad region; genes not listed).
- chr18:6,727,053–7,135,819, 12 genes, copy number 15: AP005205.3, AP005205.2, ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1, AP005062.1, SLC25A51P2.
- chr18:34,892,013–43,129,039, 82 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).
- chr18:44,039,471–49,851,059, 116 genes, copy number 8–10 (within-gene range 1–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,257. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
